Somatic mutation profile of tumor specimen TCGA-DU-A5TR-01A (aliquot TCGA-DU-A5TR-01A-11D-A289-08) from TCGA case TCGA-DU-A5TR, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 51.4 years (18,791 days).
Specimen TCGA-DU-A5TR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8980d6d9-f83a-4353-a494-20dc33505ed3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TR-10A (Blood Derived Normal), aliquot TCGA-DU-A5TR-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abb3e2ea-b6b8-4870-918b-8454a47cb064

The open-access MAF lists 36 somatic variants for this specimen: 33 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 32, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1319G>C p.C440S | Missense Mutation (SNP) | VAF 26/98 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53037970, COSV53045435; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV52221049, COSV52230042; called by muse, mutect2, varscan2
- ADAMTS2 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1199551595, COSV51076008; called by muse, mutect2, varscan2
- AMBRA1 | c.1799G>A p.W600* (on ENST00000458649 / NM_001367468.1; = p.W510* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV54052677; called by muse, mutect2, varscan2
- AOX1 | c.3493G>A p.G1165R | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53495845; called by muse, mutect2, varscan2
- ASPH | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771474720, COSV65244220; called by muse, mutect2, varscan2
- ATN1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100755598, COSV63110804; called by muse, mutect2
- ATRX | c.5224A>G p.R1742G | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64875184; called by muse, mutect2, varscan2
- C2CD5 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61724176; called by muse, mutect2, varscan2
- C2orf50 | c.16A>C p.T6P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV67510574; called by muse, varscan2
- CCNB1 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs180760005, COSV56509836; called by muse, mutect2, varscan2
- CD180 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs867380226, COSV56517687; called by muse, mutect2, varscan2
- CLCA2 | c.686T>A p.I229N | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV65286907, COSV65287247; called by muse, mutect2, varscan2
- CTCFL | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166796904, COSV99712699; called by muse, mutect2
- FIGNL1 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63553405; called by muse, mutect2, varscan2
- FPGS | c.1552A>G p.S518G | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV61227224; called by muse, mutect2, varscan2
- GANC | c.700T>C p.S234P | Missense Mutation (SNP) | VAF 57/158 reads (36%) | PolyPhen benign (0.072); catalogued as COSV58808544; called by muse, mutect2, varscan2
- GPR17 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55754847; called by muse, mutect2, varscan2
- IL33 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV67343034; called by muse, mutect2
- KLHL28 | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV61887946; called by muse, mutect2, varscan2
- NSUN5 | c.1176C>G p.H392Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV53091357; called by muse, mutect2, varscan2
- OR10A3 | c.184T>G p.F62V | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1266253836, COSV62459416; called by muse, mutect2, varscan2
- PKHD1L1 | c.8131G>A p.G2711S | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1201050500, COSV65739671; called by muse, mutect2, varscan2
- PRAMEF2 | c.221A>G p.H74R | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs1231439701, COSV53574693; called by muse, mutect2
- SLC2A5 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1485131697, COSV66236320; called by muse, mutect2, varscan2
- TGFBR2 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1444024775, CM123165, COSV55448224; called by muse, mutect2, varscan2
- TLR1 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111596029, COSV58304049; called by muse, mutect2, varscan2
- TRABD2A | c.1199C>T p.P400L (on ENST00000409520 / NM_001277053.2; = p.P351L on NM_001080824.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52857733; called by muse, mutect2, varscan2
- TTN | c.69490G>A p.V23164I (on ENST00000591111; = p.V15740I on NM_003319.4) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | PolyPhen probably damaging (0.991); catalogued as rs371306826; called by muse, mutect2, varscan2
- UTRN | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs868382624, COSV62333323; called by muse, mutect2, varscan2
- ZNF776 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57815075; called by muse, mutect2, varscan2
- MEX3D | c.726G>A p.S242= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV66311981; called by muse, mutect2, varscan2
- RHO | c.876G>A p.A292= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs145004306; called by muse, mutect2, varscan2
- TSPEAR | c.477A>G p.T159= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1555916001, COSV59959338; called by muse, mutect2, varscan2
